CCG case CUPP-B49D — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/90fb6f8e-5240-479c-a417-b08a2fea015a

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1972; Vital status: Dead; Days to death: 20 days; Year of death: 2016; Cause of death: Cancer Related.

Diagnoses (1)
1. Neoplasm, malignant, uncertain whether primary or metastatic: ICD-O-3 morphology code: 8000/9; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Lung, NOS; Classification of tumor: metastasis; Age at diagnosis: 43.6 years (15,935 days); Year of diagnosis: 2016; Method of diagnosis: Biopsy; AJCC clinical M: M1; AJCC pathologic M: M1; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Brain, NOS / Lung, NOS / Pancreas, NOS.
   Pathology details: Consistent pathology review: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Timepoint category: First Treatment.

Follow-up (1 entry)
- Days to follow up: 20 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 63 kg; Height: 170 cm; BMI: 21.8.

Exposures
- Tobacco smoking status: Smoker at Diagnosis.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B49D-NT1-A: Sample type: FFPE Scrolls; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B49D-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 75; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 5.
- Sample CUPP-B49D-TTM1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B49D-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 25; Percent tumor nuclei: 25; Percent normal cells: 15; Percent necrosis: 10; Percent stromal cells: 50; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 16; Percent neutrophil infiltration: 12.
